Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAI6, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAI6-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 7.0 cm; no rete testis and epididymis available; no angio-invasion; no invasion of tunica albuginea; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD-O-3
Seminoma NOS 9061/3
Site: @ Testis NOS C62.9
9/31/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file d807e504-2d02-4e90-b238-8fe63d791156 (TCGA-2G-AAI6-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).